Somatic mutation profile of tumor specimen ALCH-B1MI-TTP1-A (aliquot ALCH-B1MI-TTP1-A-1-0-D-A76C-36) from ALCHEMIST case ALCH-B1MI, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: female; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 64.6 years (23,601 days).
Specimen ALCH-B1MI-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 1f32e77d-6369-4aec-ad1f-1742bf154a90.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ALCH-B1MI-NB1-A (Blood Derived Normal), aliquot ALCH-B1MI-NB1-A-1-0-D-A76C-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/79c12c57-f9cd-4508-ac18-460b491acf36

The open-access MAF lists 278 somatic variants for this specimen: 190 protein-altering or splice-affecting, 51 silent, 37 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 168, Silent 51, Intron 19, Nonsense Mutation 9, Frame Shift Del 7, RNA 6, 5'UTR 4, 5'Flank 4, 3'UTR 3, Splice Site 2, Splice Region 2, Nonstop Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.34G>T p.G12C | Missense Mutation (SNP) | VAF 66/340 reads (19%) | hotspot (GDC flag); SIFT deleterious (0.04); PolyPhen probably damaging (0.991); catalogued as rs121913530, CM076251, COSV55497461, COSV55497469, COSV55497582, COSV56157736; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- NFE2L2 | c.241G>A p.G81S | Missense Mutation (SNP) | VAF 89/426 reads (21%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1553487942, COSV67960075, COSV67960449, COSV67960680; ClinVar: pathogenic; called by muse, varscan2
- BARD1 | c.2275C>T p.P759S | Missense Mutation (SNP) | VAF 48/171 reads (28%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.999); catalogued as rs1318628468; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CACNA1A | c.4888C>A p.R1630S | Missense Mutation (SNP) | VAF 78/392 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.924); catalogued as COSV100802605, COSV64199885; called by muse, mutect2, varscan2
- CCDC168 | c.11219C>G p.T3740R | Missense Mutation (SNP) | VAF 38/231 reads (16%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.673); catalogued as rs1453288232; called by muse, mutect2, varscan2
- CDH19 | c.1270A>G p.T424A | Missense Mutation (SNP) | VAF 6/29 reads (21%) | SIFT tolerated (0.06); PolyPhen benign (0.012); catalogued as COSV100052330; called by muse, mutect2, varscan2
- CELA3A | c.152G>A p.S51N | Missense Mutation (SNP) | VAF 131/1057 reads (12%) | SIFT tolerated (0.96); PolyPhen benign (0); catalogued as rs559865625; called by muse, mutect2, varscan2
- CHCHD6 | c.361C>T p.P121S | Missense Mutation (SNP) | VAF 178/841 reads (21%) | SIFT tolerated (0.4); PolyPhen benign (0.048); catalogued as rs1241286979; called by muse, mutect2, varscan2
- CHL1 | c.1485G>T p.W495C (on ENST00000397491 / NM_001253387.1; = p.W511C on NM_006614.4) | Missense Mutation (SNP) | VAF 36/187 reads (19%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.683); catalogued as rs767868503; called by muse, mutect2, varscan2
- CHL1 | c.2701G>T p.G901C (on ENST00000397491 / NM_001253387.1; = p.G917C on NM_006614.4) | Missense Mutation (SNP) | VAF 24/143 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56606200; called by muse, mutect2, varscan2
- COL24A1 | c.1322T>C p.V441A | Missense Mutation (SNP) | VAF 16/66 reads (24%) | SIFT tolerated (0.18); PolyPhen benign (0.001); catalogued as rs1169374387; called by muse, mutect2, varscan2
- COMMD3 | c.511A>T p.S171C | Missense Mutation (SNP) | VAF 6/36 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.526); catalogued as rs767793016; called by mutect2, varscan2
- CSE1L | c.1438C>G p.L480V | Missense Mutation (SNP) | VAF 10/101 reads (10%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.896); catalogued as COSV53703675; called by muse, mutect2
- CTAGE1 | c.2078C>T p.P693L | Missense Mutation (SNP) | VAF 66/372 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); catalogued as rs757233842; called by muse, mutect2, varscan2
- DCAF4L2 | c.168G>T p.R56S | Missense Mutation (SNP) | VAF 247/1035 reads (24%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.849); catalogued as COSV60478072, COSV60479243; called by muse, mutect2, varscan2
- EBF1 | c.1074G>T p.R358S | Missense Mutation (SNP) | VAF 44/266 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1166983631; called by muse, mutect2, varscan2
- ERF | c.773C>A p.S258Y | Missense Mutation (SNP) | VAF 26/101 reads (26%) | SIFT deleterious (0.01); PolyPhen benign (0.302); catalogued as COSV55896602; called by muse, mutect2, varscan2
- GEMIN6 | c.502T>A p.*168Rext*22 | Nonstop Mutation (SNP) | VAF 10/46 reads (22%) | catalogued as rs1307375217; called by muse, mutect2, varscan2
- GHR | c.1093C>A p.L365I | Missense Mutation (SNP) | VAF 83/475 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs976185500; called by muse, varscan2
- HAO1 | c.982G>A p.G328S | Missense Mutation (SNP) | VAF 32/162 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs751451932; called by muse, mutect2, varscan2
- HCN2 | c.835C>A p.P279T | Missense Mutation (SNP) | VAF 147/491 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as rs1467032996; called by muse, mutect2, varscan2
- HPGD | c.97G>A p.A33T | Missense Mutation (SNP) | VAF 190/993 reads (19%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.728); catalogued as rs374475270; called by muse, mutect2, varscan2
- IDS | c.593A>T p.D198V | Missense Mutation (SNP) | VAF 40/189 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as CM981030; called by muse, mutect2, varscan2
- IGKV1D-13 | c.301C>A p.Q101K | Missense Mutation (SNP) | VAF 14/80 reads (18%) | SIFT tolerated (0.07); PolyPhen benign (0.076); catalogued as rs756915063; called by mutect2, varscan2
- INPP5B | c.583C>T p.Q195* | Nonsense Mutation (SNP) | VAF 83/353 reads (24%) | catalogued as rs763153977; called by muse, mutect2, varscan2
- JMJD7-PLA2G4B | c.1214C>G p.P405R | Missense Mutation (SNP) | VAF 139/596 reads (23%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.572); catalogued as rs1230856813; called by muse, mutect2, varscan2
- LRRC14B | c.305G>A p.R102Q | Missense Mutation (SNP) | VAF 82/292 reads (28%) | SIFT tolerated (0.58); PolyPhen benign (0); catalogued as rs1225705221; called by muse, mutect2, varscan2
- LTBP2 | c.1489G>T p.G497W | Missense Mutation (SNP) | VAF 43/260 reads (17%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.652); catalogued as COSV56209618; called by muse, mutect2, varscan2
- MAP1LC3C | c.436C>A p.P146T | Missense Mutation (SNP) | VAF 60/134 reads (45%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.017); catalogued as COSV61803993; called by muse, mutect2
- MMP2 | c.307G>A p.G103S | Missense Mutation (SNP) | VAF 74/291 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.835); catalogued as rs764627590; called by mutect2, varscan2
- MSGN1 | c.13C>A p.R5S | Missense Mutation (SNP) | VAF 21/103 reads (20%) | SIFT tolerated (0.4); PolyPhen benign (0.012); catalogued as rs751924734, COSV55264082, COSV99808699; called by muse, mutect2, varscan2
- NDST4 | c.1006C>A p.R336S | Missense Mutation (SNP) | VAF 22/174 reads (13%) | SIFT tolerated (0.05); PolyPhen benign (0.261); catalogued as COSV52127725; called by muse, varscan2
- NLGN4X | c.1123del p.E375Kfs*3 | Frame Shift Del (DEL) | VAF 136/742 reads (18%) | catalogued as COSV52041438, COSV99319543; called by mutect2, pindel, varscan2
- OBSCN | c.23039+1G>A p.X7680_splice | Splice Site (SNP) | VAF 27/325 reads (8%) | catalogued as rs1558433988; called by muse, mutect2
- OR2M5 | c.859C>A p.P287T | Missense Mutation (SNP) | VAF 87/271 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100822895; called by muse, mutect2, varscan2
- OR4C11 | c.55C>A p.P19T | Missense Mutation (SNP) | VAF 10/34 reads (29%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.849); catalogued as COSV56352870; called by muse, mutect2, varscan2
- OR51E1 | c.808C>A p.R270S | Missense Mutation (SNP) | VAF 83/502 reads (17%) | SIFT tolerated (0.83); PolyPhen benign (0.043); catalogued as rs575981363, COSV67809895; called by muse, mutect2, varscan2
- PABPN1 | c.872G>T p.R291L | Missense Mutation (SNP) | VAF 147/997 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.982); catalogued as COSV53729794, COSV53730347; called by muse, mutect2, varscan2
- PARVG | c.974C>A p.T325K | Missense Mutation (SNP) | VAF 192/976 reads (20%) | SIFT tolerated, low confidence (0.93); PolyPhen benign (0); catalogued as rs200951064, COSV63563113; called by muse, mutect2, varscan2
- PCDHA4 | c.1612C>T p.R538C | Missense Mutation (SNP) | VAF 226/1746 reads (13%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.421); catalogued as COSV63543231; called by muse, mutect2, varscan2
- PGLYRP4 | c.145C>G p.P49A | Missense Mutation (SNP) | VAF 74/409 reads (18%) | SIFT tolerated (0.8); PolyPhen benign (0.026); catalogued as COSV100668301; called by muse, mutect2, varscan2
- PRPS1L1 | c.65G>T p.R22L | Missense Mutation (SNP) | VAF 218/1213 reads (18%) | SIFT deleterious (0.03); PolyPhen benign (0.009); catalogued as rs770382539, COSV72649976; called by muse, mutect2, varscan2
- RAI1 | c.3142G>T p.A1048S | Missense Mutation (SNP) | VAF 31/177 reads (18%) | SIFT tolerated (0.07); PolyPhen benign (0.015); catalogued as rs889706395, COSV55393449; called by muse, mutect2, varscan2
- RFX6 | c.1855G>A p.A619T | Missense Mutation (SNP) | VAF 88/393 reads (22%) | SIFT tolerated, low confidence (0.63); PolyPhen benign (0); catalogued as rs1163124155; called by muse, mutect2, varscan2
- SHROOM2 | c.2098C>G p.R700G | Missense Mutation (SNP) | VAF 117/631 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV66607208; called by muse, mutect2, varscan2
- SLC4A4 | c.2338del p.V780Cfs*15 (on ENST00000264485 / NM_001098484.3; = p.V736Cfs*15 on NM_003759.4) | Frame Shift Del (DEL) | VAF 66/385 reads (17%) | catalogued as COSV99140513; called by mutect2, pindel, varscan2
- SPACA1 | c.256G>T p.V86F | Missense Mutation (SNP) | VAF 30/180 reads (17%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.972); catalogued as COSV52760366; called by muse, varscan2
- TAGAP | c.1974C>A p.H658Q | Missense Mutation (SNP) | VAF 59/232 reads (25%) | SIFT tolerated (0.6); PolyPhen benign (0.045); catalogued as COSV100487521, COSV57852222; called by muse, mutect2, varscan2
- TBRG4 | c.1522G>T p.D508Y | Missense Mutation (SNP) | VAF 33/323 reads (10%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.899); catalogued as rs748231648, COSV99345687; called by muse, mutect2, varscan2
- THBS1 | c.247C>T p.R83W | Missense Mutation (SNP) | VAF 48/506 reads (9%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.45); catalogued as rs571353083, COSV52951604; called by muse, mutect2
- TRIM55 | c.1196C>T p.P399L | Missense Mutation (SNP) | VAF 63/291 reads (22%) | SIFT tolerated (0.31); PolyPhen benign (0.035); catalogued as rs778653151; called by muse, mutect2, varscan2
- TTBK2 | c.1453A>G p.I485V | Missense Mutation (SNP) | VAF 13/46 reads (28%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1437126507; called by muse, mutect2, varscan2
- TTC37 | c.2357A>G p.Y786C | Missense Mutation (SNP) | VAF 59/323 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100706573; called by muse, mutect2, varscan2
- USP26 | c.1126C>T p.H376Y | Missense Mutation (SNP) | VAF 30/146 reads (21%) | SIFT deleterious (0); PolyPhen benign (0.236); catalogued as COSV63708364, COSV63709713; called by muse, mutect2, varscan2
- WBP1 | c.614A>G p.Y205C | Missense Mutation (SNP) | VAF 50/221 reads (23%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.996); catalogued as rs767646471; called by muse, mutect2, varscan2
- XPNPEP1 | c.702G>T p.E234D | Missense Mutation (SNP) | VAF 36/256 reads (14%) | SIFT tolerated (0.12); PolyPhen benign (0.009); catalogued as COSV100451073; called by muse, mutect2, varscan2
- ZNF217 | c.1210G>C p.G404R | Missense Mutation (SNP) | VAF 153/595 reads (26%) | SIFT deleterious (0.01); PolyPhen benign (0.443); catalogued as COSV100184929; called by muse, mutect2, varscan2
- ZNF536 | c.167C>A p.P56H | Missense Mutation (SNP) | VAF 42/186 reads (23%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.681); catalogued as rs1314626917, COSV100834850, COSV100835743; called by muse, mutect2, varscan2
- ZNF608 | c.781G>T p.A261S | Missense Mutation (SNP) | VAF 89/541 reads (16%) | SIFT tolerated (0.23); PolyPhen benign (0.001); catalogued as COSV60436848; called by muse, mutect2, varscan2
- ZNF609 | c.108T>G p.I36M | Missense Mutation (SNP) | VAF 98/465 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV58579614; called by muse, mutect2, varscan2
- ADAMTS20 | c.5313-1G>T p.X1771_splice | Splice Site (SNP) | VAF 28/144 reads (19%) | called by muse, mutect2, varscan2
- ADCK1 | c.806G>T p.G269V | Missense Mutation (SNP) | VAF 40/600 reads (7%) | SIFT deleterious (0.04); PolyPhen benign (0.32); called by muse, mutect2
- ADGRG4 | c.8478G>T p.W2826C | Missense Mutation (SNP) | VAF 80/442 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ADGRV1 | c.994G>T p.V332F | Missense Mutation (SNP) | VAF 14/58 reads (24%) | SIFT deleterious (0.03); PolyPhen benign (0.022); called by muse, mutect2, varscan2
- ADGRV1 | c.10514A>T p.N3505I | Missense Mutation (SNP) | VAF 99/535 reads (19%) | SIFT tolerated (0.06); PolyPhen benign (0.024); called by muse, mutect2, varscan2
- AFTPH | c.2353A>G p.M785V | Missense Mutation (SNP) | VAF 54/206 reads (26%) | SIFT tolerated (1); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- AGTPBP1 | c.2353T>C p.Y785H (on ENST00000357081 / NM_001330701.2; = p.Y745H on NM_015239.2) | Missense Mutation (SNP) | VAF 18/98 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); called by muse, mutect2, varscan2
- AL592490.1 | c.1174G>T p.E392* | Nonsense Mutation (SNP) | VAF 28/187 reads (15%) | called by muse, mutect2, varscan2
- AMER1 | c.578G>T p.G193V | Missense Mutation (SNP) | VAF 6/22 reads (27%) | SIFT tolerated (0.24); PolyPhen benign (0.023); called by muse, mutect2, varscan2
- ASB15 | c.1489G>T p.V497F | Missense Mutation (SNP) | VAF 15/111 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.761); called by muse, mutect2, varscan2
- ASPHD2 | c.798dup p.G267Wfs*38 | Frame Shift Ins (INS) | VAF 31/211 reads (15%) | called by mutect2, pindel, varscan2
- ASXL3 | c.5143C>A p.P1715T | Missense Mutation (SNP) | VAF 31/271 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.024); called by muse, mutect2, varscan2
- ATG2B | c.2362G>C p.E788Q | Missense Mutation (SNP) | VAF 28/198 reads (14%) | SIFT tolerated (0.57); PolyPhen probably damaging (0.994); called by muse, varscan2
- AURKB | c.537G>T p.T179= | Splice Region (SNP) | VAF 28/143 reads (20%) | called by muse, mutect2, varscan2
- AUTS2 | c.2848G>A p.E950K | Missense Mutation (SNP) | VAF 101/926 reads (11%) | SIFT deleterious (0.03); PolyPhen benign (0.066); called by muse, mutect2, varscan2
- AUTS2 | c.3102G>A p.M1034I | Missense Mutation (SNP) | VAF 58/732 reads (8%) | SIFT tolerated (0.25); PolyPhen benign (0.006); called by muse, mutect2
- AUTS2 | c.3247G>A p.D1083N | Missense Mutation (SNP) | VAF 39/333 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- CACNA1B | c.5231T>A p.I1744N | Missense Mutation (SNP) | VAF 208/375 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); called by muse, mutect2, varscan2
- CARD11 | c.707_713del p.L236* | Frame Shift Del (DEL) | VAF 31/169 reads (18%) | called by mutect2, pindel, varscan2
- CCBE1 | c.980G>T p.G327V | Missense Mutation (SNP) | VAF 67/384 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CCDC8 | c.1132C>A p.Q378K | Missense Mutation (SNP) | VAF 360/1838 reads (20%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0); called by muse, mutect2, varscan2
- CDON | c.2971A>T p.N991Y | Missense Mutation (SNP) | VAF 83/432 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); called by muse, varscan2
- CENPF | c.2341C>T p.Q781* | Nonsense Mutation (SNP) | VAF 43/321 reads (13%) | called by muse, mutect2, varscan2
- CFAP45 | c.930G>T p.K310N | Missense Mutation (SNP) | VAF 41/223 reads (18%) | SIFT tolerated (0.11); PolyPhen benign (0.346); called by muse, mutect2, varscan2
- CFHR4 | c.894C>A p.Y298* (on ENST00000367416 / NM_001201551.2; = p.Y299* on NM_001201550.3) | Nonsense Mutation (SNP) | VAF 99/303 reads (33%) | called by muse, mutect2, varscan2
- COIL | c.633G>T p.W211C | Missense Mutation (SNP) | VAF 47/203 reads (23%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.719); called by muse, mutect2, varscan2
- COL22A1 | c.4147C>T p.P1383S | Missense Mutation (SNP) | VAF 65/397 reads (16%) | SIFT tolerated (0.11); PolyPhen benign (0.185); called by muse, mutect2, varscan2
- CRB2 | c.2047G>T p.G683C | Missense Mutation (SNP) | VAF 192/1244 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); called by muse, mutect2, varscan2
- CSMD3 | c.10556C>A p.T3519N (on ENST00000297405 / NM_001363185.1; = p.T3350N on NM_052900.3) | Missense Mutation (SNP) | VAF 71/349 reads (20%) | SIFT tolerated (0.17); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- CUBN | c.1312A>G p.S438G | Missense Mutation (SNP) | VAF 39/343 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); called by muse, mutect2, varscan2
- DDX46 | c.1335del p.P446Qfs*2 | Frame Shift Del (DEL) | VAF 17/60 reads (28%) | called by mutect2, pindel, varscan2
- DIP2C | c.3730G>T p.G1244C | Missense Mutation (SNP) | VAF 53/245 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); called by muse, mutect2, varscan2
- DNAH5 | c.730G>A p.A244T | Missense Mutation (SNP) | VAF 69/264 reads (26%) | SIFT deleterious (0.03); PolyPhen benign (0.212); called by muse, mutect2, varscan2
- EFCAB6 | c.3878G>T p.C1293F | Missense Mutation (SNP) | VAF 100/346 reads (29%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.828); called by muse, mutect2, varscan2
- ENOX2 | c.1050C>A p.H350Q (on ENST00000338144 / NM_001382520.1; = p.H321Q on NM_006375.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 61/273 reads (22%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.972); called by muse, mutect2, varscan2
- EPC1 | c.1291G>A p.G431R | Missense Mutation (SNP) | VAF 16/152 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.943); called by muse, mutect2, varscan2
- EPX | c.421T>G p.C141G | Missense Mutation (SNP) | VAF 125/448 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.948); called by muse, mutect2, varscan2
- EQTN | c.523C>A p.L175I | Missense Mutation (SNP) | VAF 30/121 reads (25%) | SIFT tolerated (0.13); PolyPhen benign (0.105); called by muse, varscan2
- ERAS | c.637A>T p.R213W | Missense Mutation (SNP) | VAF 91/301 reads (30%) | SIFT deleterious (0.01); PolyPhen benign (0.071); called by muse, mutect2, varscan2
- ESR1 | c.1007C>A p.P336H | Missense Mutation (SNP) | VAF 63/337 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.944); called by muse, mutect2, varscan2
- FAM160B1 | c.1879G>T p.E627* | Nonsense Mutation (SNP) | VAF 54/341 reads (16%) | called by muse, varscan2
- FAM199X | c.55G>C p.E19Q | Missense Mutation (SNP) | VAF 126/622 reads (20%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.969); called by muse, mutect2, varscan2
- FAM50A | c.734G>T p.G245V | Missense Mutation (SNP) | VAF 90/424 reads (21%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.943); called by muse, mutect2, varscan2
- FCGBP | c.10295G>T p.G3432V | Missense Mutation (SNP) | VAF 290/1328 reads (22%) | SIFT tolerated (0.1); PolyPhen benign (0.395); called by muse, mutect2, varscan2
- FGFRL1 | c.1225G>T p.A409S | Missense Mutation (SNP) | VAF 170/695 reads (24%) | SIFT tolerated (0.69); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- FHAD1 | c.2434G>A p.A812T | Missense Mutation (SNP) | VAF 64/347 reads (18%) | SIFT tolerated (0.37); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- FIBCD1 | c.1179C>G p.D393E | Missense Mutation (SNP) | VAF 274/533 reads (51%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- FKBP1C | c.137C>A p.P46H | Missense Mutation (SNP) | VAF 248/1330 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by mutect2, varscan2
- GABRG2 | c.1253C>T p.P418L (on ENST00000361925 / NM_001375343.1; = p.P378L on NM_000816.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 71/392 reads (18%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.476); called by muse, mutect2, varscan2
- GALNT14 | c.944G>T p.R315L | Missense Mutation (SNP) | VAF 21/127 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- GAREM2 | c.1594G>C p.D532H | Missense Mutation (SNP) | VAF 134/676 reads (20%) | SIFT deleterious (0); PolyPhen benign (0.234); called by muse, mutect2, varscan2
- GASK1A | c.1694A>G p.H565R | Missense Mutation (SNP) | VAF 56/221 reads (25%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.596); called by muse, mutect2, varscan2
- GPAT2 | c.398G>T p.G133V | Missense Mutation (SNP) | VAF 8/19 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); called by mutect2, varscan2
- GRAMD1A | c.1168G>T p.D390Y | Missense Mutation (SNP) | VAF 30/658 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); called by muse, mutect2
- GREB1L | c.3602C>A p.P1201Q | Missense Mutation (SNP) | VAF 41/166 reads (25%) | SIFT tolerated (0.12); PolyPhen benign (0.443); called by muse, mutect2, varscan2
- HECTD2 | c.2315G>C p.G772A | Missense Mutation (SNP) | VAF 21/88 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- HIVEP1 | c.7165C>T p.Q2389* | Nonsense Mutation (SNP) | VAF 110/626 reads (18%) | called by muse, mutect2, varscan2
- HOMER2 | c.914T>C p.V305A (on ENST00000304231 / NM_199330.3; = p.V294A on NM_004839.4) | Missense Mutation (SNP) | VAF 106/468 reads (23%) | SIFT deleterious (0.03); PolyPhen benign (0.335); called by muse, mutect2, varscan2
- HS3ST2 | c.31C>A p.P11T | Missense Mutation (SNP) | VAF 106/467 reads (23%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.044); called by muse, mutect2, varscan2
- ITIH5 | c.71G>T p.W24L | Missense Mutation (SNP) | VAF 189/723 reads (26%) | SIFT tolerated (0.66); PolyPhen benign (0.018); called by muse, mutect2, varscan2
- ITPKB | c.2064C>G p.I688M | Missense Mutation (SNP) | VAF 176/996 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- ITPR2 | c.7335A>T p.L2445F | Missense Mutation (SNP) | VAF 64/264 reads (24%) | SIFT tolerated (0.7); PolyPhen benign (0.206); called by muse, varscan2
- JAKMIP2 | c.794T>C p.I265T | Missense Mutation (SNP) | VAF 116/529 reads (22%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.923); called by muse, mutect2, varscan2
- KCNH7 | c.2559T>A p.D853E | Missense Mutation (SNP) | VAF 25/196 reads (13%) | SIFT tolerated (0.23); PolyPhen benign (0.074); called by muse, mutect2, varscan2
- KIF13B | c.4906G>T p.D1636Y | Missense Mutation (SNP) | VAF 50/244 reads (20%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0); called by muse, mutect2, varscan2
- LCN15 | c.59C>A p.A20D | Missense Mutation (SNP) | VAF 396/875 reads (45%) | SIFT deleterious (0); PolyPhen possibly damaging (0.5); called by muse, mutect2, varscan2
- LCNL1 | c.79C>T p.P27S | Missense Mutation (SNP) | VAF 170/947 reads (18%) | SIFT tolerated (0.43); PolyPhen benign (0.031); called by muse, mutect2, varscan2
- LHFPL1 | c.158C>A p.P53H | Missense Mutation (SNP) | VAF 158/646 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- MAP3K3 | c.1251G>T p.K417N | Missense Mutation (SNP) | VAF 140/659 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.714); called by muse, mutect2, varscan2
- MARK1 | c.730G>T p.G244C | Missense Mutation (SNP) | VAF 78/539 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- MICOS13 | c.343G>A p.A115T | Missense Mutation (SNP) | VAF 133/528 reads (25%) | SIFT deleterious (0.03); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- MID1IP1 | c.485C>A p.T162K | Missense Mutation (SNP) | VAF 190/940 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- NAT10 | c.1302G>T p.Q434H | Missense Mutation (SNP) | VAF 159/687 reads (23%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.519); called by muse, mutect2, varscan2
- NBPF4 | c.1900C>G p.Q634E | Missense Mutation (SNP) | VAF 30/193 reads (16%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- NOL6 | c.2437G>T p.E813* | Nonsense Mutation (SNP) | VAF 154/717 reads (21%) | called by muse, mutect2, varscan2
- OBSCN | c.10537G>A p.A3513T | Missense Mutation (SNP) | VAF 533/1460 reads (37%) | SIFT tolerated (0.44); PolyPhen benign (0.392); called by muse, mutect2, varscan2
- OR10X1 | c.175C>A p.L59M | Missense Mutation (SNP) | VAF 37/222 reads (17%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.998); called by muse, varscan2
- OR4Q2 | c.214C>A p.L72I | Missense Mutation (SNP) | VAF 8/33 reads (24%) | SIFT tolerated (1); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- OR56A3 | c.462del p.R155Efs*5 | Frame Shift Del (DEL) | VAF 68/462 reads (15%) | called by pindel, varscan2
- OR5T1 | c.197G>T p.W66L | Missense Mutation (SNP) | VAF 24/188 reads (13%) | SIFT tolerated (0.05); PolyPhen benign (0); called by muse, mutect2, varscan2
- OTOF | c.701C>A p.S234Y | Missense Mutation (SNP) | VAF 140/714 reads (20%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.915); called by muse, mutect2, varscan2
- OVCH1 | c.2255C>A p.A752E | Missense Mutation (SNP) | VAF 79/419 reads (19%) | SIFT deleterious (0.01); PolyPhen benign (0.067); called by muse, varscan2
- PABPC5 | c.533G>T p.G178V | Missense Mutation (SNP) | VAF 98/418 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.868); called by muse, mutect2, varscan2
- PAPPA2 | c.216del p.S73Afs*7 | Frame Shift Del (DEL) | VAF 46/306 reads (15%) | called by mutect2, pindel, varscan2
- PASD1 | c.47G>C p.S16T | Missense Mutation (SNP) | VAF 25/124 reads (20%) | SIFT tolerated (0.91); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- PCNX4 | c.2909T>G p.F970C (on ENST00000406854 / NM_001330177.2; = p.F736C on NM_022495.5) | Missense Mutation (SNP) | VAF 6/72 reads (8%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.75); called by muse, mutect2
- PGBD5 | c.270G>T p.W90C (on ENST00000525115; = p.W159C on NM_001258311.2) | Missense Mutation (SNP) | VAF 604/1716 reads (35%) | SIFT deleterious (0); PolyPhen benign (0.096); called by muse, mutect2, varscan2
- PIEZO2 | c.6636G>T p.G2212= | Splice Region (SNP) | VAF 27/172 reads (16%) | called by muse, mutect2, varscan2
- PIK3R3 | c.897A>T p.K299N | Missense Mutation (SNP) | VAF 25/93 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.909); called by muse, mutect2, varscan2
- PLXNB3 | c.3331C>A p.P1111T | Missense Mutation (SNP) | VAF 190/1011 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- PNPLA7 | c.316C>G p.P106A | Missense Mutation (SNP) | VAF 318/477 reads (67%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- PPARGC1B | c.1054C>T p.L352F | Missense Mutation (SNP) | VAF 145/868 reads (17%) | SIFT tolerated (0.07); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- PPP1R26 | c.2130G>T p.R710S | Missense Mutation (SNP) | VAF 54/513 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.951); called by muse, mutect2, varscan2
- PRKCG | c.1276A>T p.T426S | Missense Mutation (SNP) | VAF 47/920 reads (5%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.467); called by muse, mutect2
- PTGIR | c.112C>G p.L38V | Missense Mutation (SNP) | VAF 64/327 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- RASA3 | c.12G>T p.E4D | Missense Mutation (SNP) | VAF 159/717 reads (22%) | SIFT tolerated (0.51); PolyPhen benign (0); called by muse, mutect2, varscan2
- RBM20 | c.582G>C p.M194I | Missense Mutation (SNP) | VAF 58/1006 reads (6%) | SIFT tolerated (1); PolyPhen benign (0.001); called by muse, mutect2
- RDM1 | c.820G>T p.E274* | Nonsense Mutation (SNP) | VAF 72/470 reads (15%) | called by muse, mutect2, varscan2
- RTL5 | c.1189G>T p.E397* | Nonsense Mutation (SNP) | VAF 68/253 reads (27%) | called by mutect2, varscan2
- SHANK1 | c.3944C>A p.A1315D | Missense Mutation (SNP) | VAF 62/339 reads (18%) | SIFT tolerated (0.34); PolyPhen benign (0.164); called by muse, mutect2, varscan2
- SHOC2 | c.334A>G p.I112V | Missense Mutation (SNP) | VAF 57/334 reads (17%) | SIFT tolerated (0.09); PolyPhen benign (0.065); called by muse, mutect2, varscan2
- SIPA1L2 | c.1664C>A p.T555N | Missense Mutation (SNP) | VAF 82/247 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); called by muse, mutect2, varscan2
- SLC26A2 | c.595A>C p.N199H | Missense Mutation (SNP) | VAF 36/169 reads (21%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.897); called by muse, varscan2
- SLFN11 | c.812G>C p.R271T | Missense Mutation (SNP) | VAF 20/120 reads (17%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.762); called by muse, varscan2
- SPIDR | c.1198G>T p.V400L | Missense Mutation (SNP) | VAF 24/182 reads (13%) | SIFT tolerated (0.49); PolyPhen benign (0.007); called by muse, varscan2
- STAM | c.1436T>C p.V479A | Missense Mutation (SNP) | VAF 148/549 reads (27%) | SIFT tolerated (0.56); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- STAT4 | c.1352T>G p.V451G | Missense Mutation (SNP) | VAF 41/274 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); called by muse, mutect2
- STK11IP | c.1363G>T p.A455S | Missense Mutation (SNP) | VAF 151/763 reads (20%) | SIFT tolerated (0.7); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- STON2 | c.1710G>T p.Q570H (on ENST00000649389 / NM_001366849.2; = p.Q513H on NM_001256430.2 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 24/272 reads (9%) | SIFT tolerated (0.42); PolyPhen benign (0.214); called by muse, mutect2
- STRN4 | c.661A>T p.R221W | Missense Mutation (SNP) | VAF 176/790 reads (22%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.778); called by muse, mutect2, varscan2
- SYCE1 | c.74G>A p.G25E | Missense Mutation (SNP) | VAF 56/308 reads (18%) | SIFT deleterious (0.01); PolyPhen benign (0.145); called by muse, mutect2, varscan2
- SZT2 | c.4384C>T p.P1462S (on ENST00000634258 / NM_001365999.1; = p.P1405S on NM_015284.4) | Missense Mutation (SNP) | VAF 78/482 reads (16%) | SIFT tolerated (0.05); PolyPhen benign (0.061); called by muse, mutect2, varscan2
- TAF5L | c.1711T>C p.F571L | Missense Mutation (SNP) | VAF 137/783 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); called by muse, mutect2, varscan2
- TEX26 | c.218G>C p.S73T | Missense Mutation (SNP) | VAF 40/190 reads (21%) | SIFT tolerated (0.09); PolyPhen benign (0); called by muse, mutect2, varscan2
- TMEFF1 | c.518G>T p.C173F | Missense Mutation (SNP) | VAF 36/193 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); called by muse, varscan2
- TMEM132D | c.2802C>G p.F934L | Missense Mutation (SNP) | VAF 770/1038 reads (74%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); called by muse, varscan2
- TMEM210 | c.229A>C p.T77P | Missense Mutation (SNP) | VAF 105/1909 reads (6%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.067); called by muse, mutect2
- TNS3 | c.1346G>C p.S449T | Missense Mutation (SNP) | VAF 242/1117 reads (22%) | SIFT tolerated (0.06); PolyPhen benign (0.058); called by muse, mutect2, varscan2
- TRIM33 | c.961G>A p.G321S | Missense Mutation (SNP) | VAF 18/130 reads (14%) | SIFT tolerated (0.85); PolyPhen benign (0.024); called by muse, mutect2, varscan2
- TSPOAP1 | c.587C>A p.P196H | Missense Mutation (SNP) | VAF 54/227 reads (24%) | SIFT tolerated (0.08); PolyPhen benign (0.079); called by muse, mutect2, varscan2
- UAP1L1 | c.1520C>T p.S507F | Missense Mutation (SNP) | VAF 246/876 reads (28%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0); called by muse, varscan2
- UGT8 | c.370A>T p.I124F | Missense Mutation (SNP) | VAF 28/129 reads (22%) | SIFT deleterious (0.01); PolyPhen benign (0.062); called by muse, mutect2, varscan2
- USP11 | c.2880G>T p.M960I (on ENST00000218348; = p.M917I on NM_001371072.1) | Missense Mutation (SNP) | VAF 129/712 reads (18%) | SIFT deleterious (0.01); PolyPhen benign (0); called by muse, mutect2, varscan2
- USP11 | c.2881G>T p.D961Y (on ENST00000218348; = p.D918Y on NM_001371072.1) | Missense Mutation (SNP) | VAF 127/709 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.467); called by muse, mutect2, varscan2
- USP20 | c.1287G>T p.L429F | Missense Mutation (SNP) | VAF 316/612 reads (52%) | SIFT tolerated (0.52); PolyPhen benign (0.224); called by muse, mutect2, varscan2
- USP38 | c.3017C>T p.S1006L | Missense Mutation (SNP) | VAF 73/375 reads (19%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- WDR62 | c.1414C>G p.L472V | Missense Mutation (SNP) | VAF 125/1049 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- ZIC5 | c.1619A>C p.K540T | Missense Mutation (SNP) | VAF 82/362 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- ZRANB1 | c.485del p.N162Tfs*22 | Frame Shift Del (DEL) | VAF 41/207 reads (20%) | called by mutect2, pindel, varscan2
- ZSCAN1 | c.865G>T p.G289W | Missense Mutation (SNP) | VAF 213/906 reads (24%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.744); called by muse, mutect2, varscan2
- ABCG8 | c.222C>A p.P74= | Silent (SNP) | VAF 71/395 reads (18%) | catalogued as COSV99699371; called by muse, mutect2, varscan2
- ARID4A | c.3579A>T p.L1193= | Silent (SNP) | VAF 15/85 reads (18%) | called by muse, mutect2, varscan2
- AUTS2 | c.3711G>A p.T1237= | Silent (SNP) | VAF 5/45 reads (11%) | catalogued as rs757776766; called by mutect2, varscan2
- BCHE | c.891C>T p.P297= | Silent (SNP) | VAF 13/80 reads (16%) | called by muse, mutect2, varscan2
- BEND5 | c.219G>A p.A73= | Silent (SNP) | VAF 26/116 reads (22%) | called by muse, mutect2, varscan2
- CALR3 | c.378G>T p.S126= | Silent (SNP) | VAF 29/140 reads (21%) | called by muse, mutect2, varscan2
- CAMSAP3 | c.3348C>T p.P1116= | Silent (SNP) | VAF 133/615 reads (22%) | catalogued as rs1254884625; called by muse, mutect2, varscan2
- CSMD2 | c.10149C>T p.F3383= | Silent (SNP) | VAF 150/799 reads (19%) | catalogued as rs772225864, COSV53877528; called by muse, mutect2, varscan2
- DCUN1D2 | c.651G>T p.L217= | Silent (SNP) | VAF 41/251 reads (16%) | called by muse, mutect2, varscan2
- DNAH10 | c.5598G>C p.L1866= (on ENST00000409039; = p.L1805= on NM_207437.3) | Silent (SNP) | VAF 30/348 reads (9%) | called by muse, mutect2
- DNAI2 | c.147G>T p.T49= | Silent (SNP) | VAF 158/649 reads (24%) | catalogued as rs369017940; called by muse, mutect2, varscan2
- EPRS1 | c.4035A>G p.L1345= | Silent (SNP) | VAF 52/153 reads (34%) | called by muse, mutect2, varscan2
- FRAS1 | c.5151C>T p.S1717= | Silent (SNP) | VAF 12/62 reads (19%) | called by muse, mutect2, varscan2
- FRMD3 | c.351G>A p.L117= | Silent (SNP) | VAF 14/134 reads (10%) | called by muse, mutect2
- FUT11 | c.201A>T p.P67= | Silent (SNP) | VAF 21/108 reads (19%) | called by muse, mutect2, varscan2
- GABRA5 | c.954C>A p.T318= | Silent (SNP) | VAF 142/637 reads (22%) | called by muse, mutect2, varscan2
- GAD1 | c.1170C>T p.L390= | Silent (SNP) | VAF 162/843 reads (19%) | called by muse, mutect2, varscan2
- GOLGA3 | c.1815C>G p.T605= | Silent (SNP) | VAF 105/344 reads (31%) | catalogued as COSV52630254; called by muse, varscan2
- HMCN2 | c.1872G>A p.V624= | Silent (SNP) | VAF 215/1833 reads (12%) | called by muse, mutect2, varscan2
- INSR | c.3880C>T p.L1294= | Silent (SNP) | VAF 124/395 reads (31%) | called by muse, mutect2, varscan2
- KCNH7 | c.3375C>A p.S1125= | Silent (SNP) | VAF 27/106 reads (25%) | catalogued as COSV59810083; called by muse, mutect2, varscan2
- KCNJ12 | c.21C>A p.A7= | Silent (SNP) | VAF 96/1253 reads (8%) | called by muse, mutect2
- MAGEB18 | c.801T>C p.Y267= | Silent (SNP) | VAF 42/155 reads (27%) | called by muse, mutect2, varscan2
- MASP1 | c.1602C>G p.G534= | Silent (SNP) | VAF 130/624 reads (21%) | called by muse, varscan2
- MED12L | c.3033C>G p.V1011= | Silent (SNP) | VAF 74/338 reads (22%) | called by muse, varscan2
- MEX3C | c.1770C>T p.S590= | Silent (SNP) | VAF 35/180 reads (19%) | called by muse, mutect2, varscan2
- MPPED1 | c.336G>T p.V112= | Silent (SNP) | VAF 170/845 reads (20%) | called by muse, mutect2
- MUC17 | c.11775T>A p.S3925= | Silent (SNP) | VAF 70/317 reads (22%) | called by muse, varscan2
- NALCN | c.444G>A p.L148= | Silent (SNP) | VAF 67/424 reads (16%) | catalogued as rs1260179546, COSV51933317; called by muse, mutect2, varscan2
- NDUFAB1 | c.42C>T p.P14= | Silent (SNP) | VAF 231/1147 reads (20%) | catalogued as rs769794674; called by muse, mutect2, varscan2
- NHS | c.306G>T p.A102= | Silent (SNP) | VAF 137/525 reads (26%) | called by muse, mutect2, varscan2
- NPB | c.90G>A p.A30= | Silent (SNP) | VAF 26/137 reads (19%) | called by muse, mutect2, varscan2
- OR6N1 | c.924T>A p.I308= | Silent (SNP) | VAF 26/72 reads (36%) | called by muse, varscan2
- OR9A4 | c.321G>A p.V107= | Silent (SNP) | VAF 46/264 reads (17%) | catalogued as rs1554439050, COSV71885182; called by muse, mutect2, varscan2
- PCDH17 | c.528C>T p.H176= | Silent (SNP) | VAF 267/1053 reads (25%) | catalogued as rs768753813; called by muse, mutect2, varscan2
- PDHA2 | c.741C>T p.I247= | Silent (SNP) | VAF 22/302 reads (7%) | catalogued as COSV54780112; called by muse, mutect2
- PTGIR | c.111C>A p.I37= | Silent (SNP) | VAF 63/325 reads (19%) | called by muse, mutect2, varscan2
- SHANK1 | c.3945C>A p.A1315= | Silent (SNP) | VAF 62/337 reads (18%) | catalogued as COSV99521752; called by muse, mutect2, varscan2
- SOAT1 | c.1050G>T p.R350= | Silent (SNP) | VAF 112/354 reads (32%) | called by muse, mutect2, varscan2
- SPART | c.789C>T p.N263= | Silent (SNP) | VAF 32/155 reads (21%) | catalogued as rs1338012047; called by muse, mutect2, varscan2
- STARD8 | c.3022C>A p.R1008= | Silent (SNP) | VAF 139/827 reads (17%) | called by muse, mutect2, varscan2
- STAT4 | c.1350T>A p.P450= | Silent (SNP) | VAF 41/269 reads (15%) | called by muse, mutect2
- TCP11X2 | c.801C>G p.S267= | Silent (SNP) | VAF 131/1331 reads (10%) | called by muse, mutect2, varscan2
- TENM1 | c.873T>A p.P291= | Silent (SNP) | VAF 40/206 reads (19%) | called by muse, mutect2, varscan2
- TEX55 | c.1455T>C p.Y485= | Silent (SNP) | VAF 36/173 reads (21%) | called by muse, mutect2, varscan2
- TMEM236 | c.702G>T p.R234= | Silent (SNP) | VAF 227/1110 reads (20%) | called by muse, mutect2, varscan2
- TSC2 | c.1534C>T p.L512= | Silent (SNP) | VAF 74/928 reads (8%) | called by muse, mutect2
- TUBGCP6 | c.5064C>T p.I1688= | Silent (SNP) | VAF 117/1728 reads (7%) | catalogued as rs1204157696; called by muse, mutect2
- UAP1L1 | c.1221C>T p.S407= | Silent (SNP) | VAF 321/1152 reads (28%) | catalogued as rs761260195; called by muse, mutect2, varscan2
- WDFY3 | c.4245G>T p.L1415= | Silent (SNP) | VAF 71/342 reads (21%) | called by muse, mutect2, varscan2
- WFIKKN1 | c.246C>T p.G82= | Silent (SNP) | VAF 38/408 reads (9%) | catalogued as COSV99937992; called by muse, mutect2
- AC092718.9 | chr16:81148248 C>A | 5'Flank (SNP) | VAF 64/255 reads (25%) | catalogued as rs1407296208; called by muse, mutect2, varscan2
- AC244517.10 | c.36-8844C>T | Intron (SNP) | VAF 310/1535 reads (20%) | called by muse, mutect2, varscan2
- ACOT9 | c.-18G>T | 5'UTR (SNP) | VAF 55/472 reads (12%) | called by muse, mutect2, varscan2
- AIDA | c.110+29G>A | Intron (SNP) | VAF 151/1021 reads (15%) | called by muse, mutect2, varscan2
- ALS2 | c.3703-1918G>T | Intron (SNP) | VAF 22/170 reads (13%) | called by muse, mutect2, varscan2
- ANXA8 | c.*151G>T | 3'UTR (SNP) | VAF 169/902 reads (19%) | called by muse, mutect2, varscan2
- ASIC4 | c.1018+42T>A | Intron (SNP) | VAF 31/114 reads (27%) | called by muse, mutect2, varscan2
- ATP5PO | c.441+595T>C | Intron (SNP) | VAF 22/515 reads (4%) | called by muse, mutect2
- C19orf12 | chr19:29701425 C>T | 3'Flank (SNP) | VAF 43/183 reads (23%) | catalogued as rs748177339; called by muse, varscan2
- CATSPER4 | c.1365+46T>C | Intron (SNP) | VAF 214/1076 reads (20%) | called by mutect2, varscan2
- CCDC162P | n.3249T>A | RNA (SNP) | VAF 11/85 reads (13%) | called by muse, mutect2, varscan2
- CCDC42 | c.*62T>G | 3'UTR (SNP) | VAF 71/297 reads (24%) | called by muse, mutect2, varscan2
- CDC37P1 | n.792C>A | RNA (SNP) | VAF 15/67 reads (22%) | catalogued as rs757223540; called by muse, mutect2, varscan2
- CHTF18 | chr16:788406 C>T | 5'Flank (SNP) | VAF 8/37 reads (22%) | called by mutect2, varscan2
- ECT2L | c.*8C>T | 3'UTR (SNP) | VAF 68/342 reads (20%) | catalogued as rs1562501552; called by muse, varscan2
- GLTPP1 | n.311T>G | RNA (SNP) | VAF 78/401 reads (19%) | called by muse, mutect2
- IGKV1-13 | n.302C>A | RNA (SNP) | VAF 70/933 reads (8%) | called by muse, mutect2
- ITGB8 | c.636-38A>T | Intron (SNP) | VAF 32/143 reads (22%) | called by muse, mutect2, varscan2
- KCTD1 | c.-15-46753C>T | Intron (SNP) | VAF 34/116 reads (29%) | called by muse, mutect2, varscan2
- KCTD3 | c.626+996G>C | Intron (SNP) | VAF 16/374 reads (4%) | catalogued as rs1404833015; called by muse, mutect2
- LAMP1 | c.-16C>T | 5'UTR (SNP) | VAF 28/131 reads (21%) | catalogued as rs1343313591; called by muse, mutect2, varscan2
- LSP1 | c.54-13337G>T | Intron (SNP) | VAF 178/719 reads (25%) | called by muse, mutect2, varscan2
- MPP1 | c.102+454C>A | Intron (SNP) | VAF 106/477 reads (22%) | called by muse, mutect2, varscan2
- NCAM1 | chr11:112961409 C>T | 5'Flank (SNP) | VAF 42/898 reads (5%) | called by muse, mutect2
- NEK10 | c.2091-13175C>A | Intron (SNP) | VAF 34/168 reads (20%) | catalogued as rs867808214; called by muse, mutect2
- NOC2LP2 | n.1410G>T | RNA (SNP) | VAF 223/1092 reads (20%) | called by muse, mutect2, varscan2
- NXF5 | n.1940G>A | RNA (SNP) | VAF 60/260 reads (23%) | called by muse, varscan2
- PCTP | c.141+134G>T | Intron (SNP) | VAF 44/209 reads (21%) | called by muse, mutect2, varscan2
- PDE2A | c.144+6195C>A | Intron (SNP) | VAF 58/347 reads (17%) | called by muse, mutect2, varscan2
- PML | c.-38C>G | 5'UTR (SNP) | VAF 167/690 reads (24%) | called by muse, mutect2, varscan2
- PTGDR | c.846+810C>A | Intron (SNP) | VAF 37/298 reads (12%) | called by muse, mutect2, varscan2
- RHBDF2 | c.556-17G>T | Intron (SNP) | VAF 24/110 reads (22%) | catalogued as rs373495992; called by muse, mutect2, varscan2
- RNA5-8SP2 | chr16:34159700 G>C | 5'Flank (SNP) | VAF 87/455 reads (19%) | called by muse, mutect2, varscan2
- SLC2A1 | c.-45C>T | 5'UTR (SNP) | VAF 142/654 reads (22%) | called by muse, mutect2, varscan2
- SLC3A2 | c.299-4231A>G | Intron (SNP) | VAF 11/144 reads (8%) | catalogued as rs1480463244; called by muse, mutect2
- STARD8 | c.-7-1009T>C | Intron (SNP) | VAF 53/249 reads (21%) | called by muse, mutect2, varscan2
- UAP1L1 | c.1431+16C>T | Intron (SNP) | VAF 305/1122 reads (27%) | called by muse, mutect2, varscan2
